Surgical pathology report (de-identified scan), TCGA case TCGA-B2-5635, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-B2-5635-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

SPECIMEN

Right kidney

CLINICAL NOTES

PRE-OP DIAGNOSIS: Right renal mass

GROSS DESCRIPTION

Received fresh in a container labeled "right kidney" is a 762 gm, 18 x 11.5 x 8.5 cm, kidney, with attached probe patent 5 cm long segment of ureter averaging 0.4 cm in diameter. There is an irregular 4 x 1.4 x 0.3 cm fragment of yellow-orange adrenal tissue situated within the perirenal adipose tissue. Discussion with [REDACTED] confirms that this is only a portion of the adrenal gland. The kidney itself spans an area 11.5 x 7 x 5.5 cm. There is a smooth tan-pink capsule which strips with relative ease. There is a spherical 3 cm in diameter circumscribed yellow-orange lesion within the upper portion of the kidney. The tumor grossly appears confined to the kidney, and is 2 cm from the closest surface. Per the clinical request, a portion of tumor and of normal kidney are submitted for tissue procurement. The renal pelvis is smooth, glistening, and tan-white. The uninvolved renal parenchyma is red-brown with a well defined corticomedullary junction, with a maximal cortical thickness of 1.4 cm. No additional focal lesions are identified. RS-10, following fixation.

BLOCK SUMMARY: 1 - vascular and ureteral margins; 2-6 - tumor, including relationship to surface of specimen and uninvolved parenchyma; 7 - renal pelvis; 8,9 - kidney away from tumor; 10 - adrenal gland. [REDACTED]

[REDACTED]

[page 2 of 2]
MICROSCOPIC DESCRIPTION

Histologic type: Clear cell renal cell carcinoma
Histologic grade (Fuhrman Nuclear Grade): 2
Primary tumor (pT): pT1a. The tumor is 3 cm in greatest dimension and is limited to the kidney.
Margins of resection: Negative
Regional lymph nodes (pN): pNX
Distant metastasis (pM): pMX
Adrenal gland: Negative for tumor
Vascular invasion: Not identified
Non-neoplastic kidney: There are sclerotic glomeruli and chronic inflammation in the parenchyma immediately surrounding the tumor, but these changes are not seen significantly in the parenchyma away from the mass. There is some pigment in tubular cells, which may be lipofuscin. This pigment does not stain for iron.

4,18

DIAGNOSIS

Kidney and adrenal gland, right, excision

- Clear cell renal cell carcinoma, 3 cm in greatest dimension, limited to kidney, margins negative for malignancy.
- Portion of adrenal gland, negative for tumor.

--- End Of Report ---

Source: NCI Genomic Data Commons file cd4af080-acb6-47f7-919f-d3337d6df652 (TCGA-B2-5635.5D8436B6-4098-422C-BAFB-7B48F3EA5741.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).